Gene-level copy-number profile of tumor specimen MP2PRT-PAVWVM-TMP1-A from MP2PRT case MP2PRT-PAVWVM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,389 days).
Specimen MP2PRT-PAVWVM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d7368133-c000-4ebf-b8ad-658ffb148c21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVWVM-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/91b3cd59-d7ae-496e-98ad-65b6dcdac5f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 635; copy number 2: 41,662; copy number 3: 14,600; copy number 4: 1,998; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,192,500–89,192,752, 1 gene (within-gene range 0–1): IGKV3-25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,583,731–105,669,843, 8 genes, copy number 5 (within-gene range 3–5): IGHA2, IGHE, IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.

Autosomal genes at a single copy (total copy number 1): 123. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
